Gene-level copy-number profile of tumor specimen TCGA-AX-A1CF-01A from TCGA case TCGA-AX-A1CF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 69.3 years (25,300 days).
Specimen TCGA-AX-A1CF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.3b55db21-08fe-4fcc-a260-261396556323.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A1CF-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff4d1f45-f3df-40fa-969e-711b6e91bf14

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 128; copy number 2: 20,068; copy number 3: 5,318; copy number 4: 25,329; copy number 5: 1,944; copy number 6: 2,877; copy number 7: 2,720; copy number 8: 1,021; copy number 9: 83; copy number 10: 273; copy number 12: 30; copy number 13: 7; copy number 21: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A1CF-01A-11D-A134-01): tumor purity 0.76, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:129,576,132–130,443,067, 10 genes (within-gene range 0–4): ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A.
- chr18:56,651,343–57,029,811, 1 gene (within-gene range 0–2): WDR7.
- chr18:56,872,668–56,957,469, 2 genes: AC012301.1, U3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 395 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:111,292,719–114,310,288, 76 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).
- chr3:114,314,501–114,529,452, 4 genes, copy number 9–12: AC093010.2, MIR568, ZBTB20-AS1, ZBTB20-AS5.
- chr4:134,932,889–135,371,924, 8 genes, copy number 9: AC104619.2, AC104619.4, AC104619.1, AC104619.3, AC107463.1, LINC02485, U6, KRT18P54.
- chr6:23,649,496–29,457,071, 273 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr11:29,713,909–31,790,324, 21 genes, copy number 12–21 (within-gene range 7–21): AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1.
- chr11:101,029,624–102,110,457, 13 genes, copy number 9: PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2.

Autosomal genes at a single copy (total copy number 1): 128. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
